Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPZ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPZ-01A (Primary Tumor).

[page 1 of 3]
TSS Patient ID:

Surgical Date:

Gross Description: Whipple, FS: Received is a pancreaticoduodenectomy specimen that consists of duodenum, pancreas, and peripancreatic fat. The duodenum measures 20.5 cm in length x 4 cm in average diameter. Both ends are received stapled shut. The serosa is smooth, red, and grossly unremarkable. The staples are removed and the duodenum is opened to reveal uniformly dusky brown mucosa in the distal one-third of the specimen. Of note, the common bile duct and the main pancreatic ducts have two separate ampullae separated by approximately 0.2 cm. There is a 0.7 x 0.5 x 0.2-cm, granular, red-tan lesion adjacent to the ampullae. The proximal duodenal mucosa is significant for several punctate hemorrhages. There is a blue stent protruding through the common bile duct ampulla.

The pancreas measures 10 x 6 x 4 cm. The specimen is oriented as follows: looped blue at portal vein groove, long blue stitch at superior mesenteric artery margin, and long single black stitch at deep radial margin. The entire radial margin of the pancreas is inked black. The neck is shaved en face and used for frozen section diagnosis and is resubmitted in toto. The new "untrue" pancreatic neck margin is inked orange for orientation. The specimen is serially sectioned to reveal a 3.8 x 3 x 3-cm, ill-defined, indurated, yellow-white mass that focally abuts the black-inked radial margin and grossly extends into the peripancreatic fat. The mass is 0.6 cm from the pancreatic neck margin and 0.5 cm from the ampulla. In the mid portion of the specimen, the mass surrounds and compresses the main pancreatic duct to a diameter of 0.1. The main pancreatic duct is probe

ICD-5-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas-head Q25.0
05/16/14

[page 2 of 3]
patent through the ampulla. Similarly, the mass centrally compresses the common bile duct that is probe patent, through the blue stent, to the ampulla. Distally, both the main pancreatic and the common bile ducts are dilated. A portion of the tumor is sent to tumor bank and

The peripancreatic fat is carefully dissected to reveal 12 possible lymph nodes. Representative sections are submitted including all possible lymph nodes.

Microscopic Description:

Diagnosis Details: C: Whipple, resection:

- Invasive pancreatic adenocarcinoma, grade 3 of 4, 3.8 cm in maximum dimension (see Pathology Staging Summary below)
- Surgical margins, including superior mesenteric artery margin, portal vein groove, and deep radial margins are negative for malignancy (tumor extends to 0.2 cm from portal vein groove)
- Metastatic adenocarcinoma in one of twelve lymph nodes
- Overall stage: pT3 N1 Mx

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 3.8 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: 1/12 positive for metastasis (Regional 1/12)

[page 3 of 3]
Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 01018d44-358f-4898-9aca-cdbc5f2f26b4 (TCGA-FB-AAPZ.8A05CF44-CB88-4554-BFE0-1C7DBEC53C6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).